Somatic mutation profile of tumor specimen MMRF_2176_1_BM_CD138pos (aliquot MMRF_2176_1_BM_CD138pos_T1_KHS5U_L08703) from MMRF case MMRF_2176, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 45.0 years (16,425 days).
Specimen MMRF_2176_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 85f94647-8c37-440b-a759-0e3c01426089.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2176_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2176_1_PB_Whole_C3_KHS5U_L08702; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6f03636a-6dd4-423e-b5e1-dce42a15f532

The open-access MAF lists 112 somatic variants for this specimen: 48 protein-altering or splice-affecting, 13 silent, 51 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, 3'UTR 29, Silent 13, Intron 9, Nonsense Mutation 5, 5'Flank 5, 3'Flank 4, 5'UTR 2, RNA 2, In Frame Del 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAIAP2L2 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.025); catalogued as rs1347403345; called by muse, mutect2, varscan2
- C2orf78 | c.2225C>T p.A742V | Missense Mutation (SNP) | VAF 9/136 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV68519272; called by muse, mutect2
- GPRASP2 | c.1684C>T p.R562W | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.948); catalogued as rs17284956, COSV104407789; called by muse, mutect2, varscan2
- IDO2 | c.1008T>G p.C336W (on ENST00000389060; = p.C349W on NM_194294.2) | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58424021; called by muse, mutect2, varscan2
- IGLV1-51 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 26/40 reads (65%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.905); catalogued as rs373561432; called by muse, varscan2
- IGLV1-51 | c.173A>G p.Q58R | Missense Mutation (SNP) | VAF 46/62 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.501); catalogued as rs559658628; called by muse, varscan2
- IGLV1-51 | c.174G>C p.Q58H | Missense Mutation (SNP) | VAF 47/63 reads (75%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs113403557; called by muse, varscan2
- IGLV4-60 | c.353G>A p.S118N | Missense Mutation (SNP) | VAF 33/43 reads (77%) | SIFT tolerated (0.11); PolyPhen benign (0.051); catalogued as rs192463945; called by muse, mutect2, varscan2
- IGLV4-69 | c.148A>T p.S50C | Missense Mutation (SNP) | VAF 58/68 reads (85%) | SIFT tolerated (0.05); PolyPhen benign (0.071); catalogued as rs374276286; called by muse, mutect2, varscan2
- IL7R | c.1004C>T p.S335F | Missense Mutation (SNP) | VAF 10/293 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.817); catalogued as COSV100286734; called by muse, mutect2
- LPO | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1352769519, COSV99228960; called by muse, mutect2, varscan2
- OR4M1 | c.927G>T p.L309F | Missense Mutation (SNP) | VAF 108/213 reads (51%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV60061394, COSV60063199; called by muse, mutect2, varscan2
- OR6F1 | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 101/236 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.195); catalogued as rs868546565, COSV57466823, COSV57468642; called by muse, mutect2, varscan2
- TYK2 | c.2203G>A p.V735M | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1473534133; called by muse, mutect2, varscan2
- USP29 | c.1684G>T p.V562F | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.944); catalogued as COSV54143928; called by muse, mutect2
- VPS13D | c.12394C>T p.R4132W | Missense Mutation (SNP) | VAF 71/158 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1291732470; called by muse, mutect2, varscan2
- VWDE | c.2164T>C p.S722P | Missense Mutation (SNP) | VAF 52/94 reads (55%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1413097888; called by muse, mutect2, varscan2
- ARAF | c.1210G>A p.V404I | Missense Mutation (SNP) | VAF 45/82 reads (55%) | SIFT tolerated (0.93); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- C2orf78 | c.2224G>T p.A742S | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2
- CBR3 | c.202C>T p.Q68* | Nonsense Mutation (SNP) | VAF 27/54 reads (50%) | called by muse, mutect2, varscan2
- CCDC178 | c.1277A>T p.K426I | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.316); called by muse, mutect2
- CDK6 | c.265G>T p.D89Y | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- CRB1 | c.2236C>T p.L746F | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.037); called by muse, varscan2
- DNMT3A | c.1649G>T p.G550V | Missense Mutation (SNP) | VAF 64/144 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- EDC4 | c.3018G>T p.E1006D | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- EXOC3L4 | c.1066G>C p.A356P | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.005); called by muse, mutect2
- FGFR3 | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.37); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FIZ1 | c.998G>A p.C333Y | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- GCLC | c.267G>A p.W89* (on ENST00000643939; = p.W93* on NM_001498.4) | Nonsense Mutation (SNP) | VAF 32/57 reads (56%) | called by muse, mutect2, varscan2
- GRM5 | c.482T>A p.L161* | Nonsense Mutation (SNP) | VAF 6/150 reads (4%) | called by muse, mutect2
- GRM8 | c.2406dup p.G803Wfs*73 | Frame Shift Ins (INS) | VAF 43/111 reads (39%) | called by mutect2, pindel, varscan2
- HDX | c.1224A>C p.R408S | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- IGHV1-69D | c.229G>T p.A77S | Missense Mutation (SNP) | VAF 54/166 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, varscan2
- KIRREL2 | c.491G>T p.G164V | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- LIMCH1 | c.395G>A p.W132* | Nonsense Mutation (SNP) | VAF 29/200 reads (15%) | called by muse, mutect2, varscan2
- MAP7D1 | c.2113C>T p.R705W | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MRPL37 | c.235G>A p.D79N | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- MUC19 | c.764C>A p.S255Y | Missense Mutation (SNP) | VAF 53/109 reads (49%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- MX2 | c.176_180del p.L59Qfs*42 | Frame Shift Del (DEL) | VAF 26/83 reads (31%) | called by mutect2, pindel, varscan2
- NTS | c.99A>C p.L33F | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- PRIMA1 | c.258G>C p.E86D | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.79); called by muse, mutect2
- RADX | c.370A>T p.K124* | Nonsense Mutation (SNP) | VAF 19/69 reads (28%) | called by muse, mutect2, varscan2
- RLIM | c.1054A>G p.N352D | Missense Mutation (SNP) | VAF 67/136 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SORCS2 | c.3310A>T p.R1104W | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- SPEG | c.6317G>A p.R2106Q | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- VPREB3 | c.227A>G p.D76G | Missense Mutation (SNP) | VAF 82/97 reads (85%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- ZNF292 | c.2907_2939del p.H971_L981del | In Frame Del (DEL) | VAF 44/150 reads (29%) | called by mutect2, pindel
- ZNF296 | c.1208T>G p.V403G | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- CBLN2 | c.270C>T p.S90= | Silent (SNP) | VAF 24/46 reads (52%) | catalogued as COSV99504324; called by muse, mutect2, varscan2
- COL4A3 | c.3903T>C p.G1301= | Silent (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2
- FFAR3 | c.729G>A p.V243= | Silent (SNP) | VAF 53/187 reads (28%) | catalogued as COSV100588303; called by muse, mutect2, varscan2
- IGHV2-70D | c.78T>C p.S26= | Silent (SNP) | VAF 24/90 reads (27%) | called by muse, varscan2
- MYH2 | c.4311T>C p.D1437= | Silent (SNP) | VAF 48/108 reads (44%) | called by muse, mutect2, varscan2
- OR1Q1 | c.855G>A p.L285= | Silent (SNP) | VAF 70/141 reads (50%) | called by muse, mutect2, varscan2
- POU5F2 | c.72G>A p.P24= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as rs1477132565, COSV67940273; called by muse, mutect2, varscan2
- PPP4R3C | c.738G>A p.A246= | Silent (SNP) | VAF 27/49 reads (55%) | catalogued as rs184576865; called by muse, mutect2, varscan2
- SBNO2 | c.2166G>T p.V722= | Silent (SNP) | VAF 27/65 reads (42%) | catalogued as rs761219169; called by muse, mutect2, varscan2
- SLC7A6 | c.1404T>G p.G468= | Silent (SNP) | VAF 17/87 reads (20%) | called by muse, mutect2, varscan2
- SPAG16 | c.1704G>A p.V568= | Silent (SNP) | VAF 10/130 reads (8%) | catalogued as COSV59113844; called by muse, mutect2
- SPATA31E1 | c.2310C>A p.A770= | Silent (SNP) | VAF 17/157 reads (11%) | catalogued as COSV100350382; called by muse, mutect2, varscan2
- TAS2R14 | c.657C>T p.S219= | Silent (SNP) | VAF 57/137 reads (42%) | catalogued as rs367647949; called by muse, mutect2, varscan2
- AFDN | chr6:167976581 T>C | 3'Flank (SNP) | VAF 7/36 reads (19%) | catalogued as rs752980720; called by muse, varscan2
- AGTR1 | c.*347A>C | 3'UTR (SNP) | VAF 18/45 reads (40%) | called by muse, mutect2, varscan2
- ANKRD54 | c.*294C>G | 3'UTR (SNP) | VAF 6/110 reads (5%) | called by muse, mutect2
- ANKRD54 | c.*55C>G | 3'UTR (SNP) | VAF 5/139 reads (4%) | catalogued as COSV53235559; called by muse, mutect2
- AQP2 | c.*274G>T | 3'UTR (SNP) | VAF 14/53 reads (26%) | called by muse, mutect2, varscan2
- ATP11C | c.*1283A>G | 3'UTR (SNP) | VAF 40/79 reads (51%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021401 G>A | 5'Flank (SNP) | VAF 30/72 reads (42%) | catalogued as rs547304687, COSV55852870; called by muse, mutect2, varscan2
- BMP2KL | n.825C>A | RNA (SNP) | VAF 41/68 reads (60%) | called by muse, mutect2, varscan2
- C2orf68 | c.107+18G>A | Intron (SNP) | VAF 41/87 reads (47%) | catalogued as rs760438050; called by muse, mutect2, varscan2
- CCSAP | c.*2033A>C | 3'UTR (SNP) | VAF 48/95 reads (51%) | called by muse, mutect2, varscan2
- CLU | c.*55G>T | 3'UTR (SNP) | VAF 73/95 reads (77%) | called by muse, mutect2, varscan2
- CTSA | chr20:45891322 A>G | 5'Flank (SNP) | VAF 37/71 reads (52%) | called by muse, mutect2, varscan2
- DBNL | c.*5807G>A | 3'UTR (SNP) | VAF 39/76 reads (51%) | called by muse, mutect2, varscan2
- DEGS1 | c.*48A>G | 3'UTR (SNP) | VAF 20/38 reads (53%) | called by muse, mutect2, varscan2
- EDARADD | c.*392C>T | 3'UTR (SNP) | VAF 6/116 reads (5%) | called by muse, mutect2
- ELOVL2 | c.*829T>G | 3'UTR (SNP) | VAF 22/51 reads (43%) | called by muse, mutect2, varscan2
- GABRB3 | c.*1920T>C | 3'UTR (SNP) | VAF 13/41 reads (32%) | catalogued as rs889905213; called by muse, mutect2, varscan2
- GCFC2 | c.*217G>A | 3'UTR (SNP) | VAF 31/59 reads (53%) | called by muse, mutect2, varscan2
- GNA12 | c.*1042G>A | 3'UTR (SNP) | VAF 24/53 reads (45%) | catalogued as rs762437008; called by muse, mutect2, varscan2
- H2AC11 | c.-8C>T | 5'UTR (SNP) | VAF 44/92 reads (48%) | catalogued as rs375274305; called by muse, mutect2, varscan2
- HMGB3 | c.*2655del | 3'UTR (DEL) | VAF 4/39 reads (10%) | catalogued as rs1212403467, COSV57486622; called by pindel, varscan2*
- IGHJ6 | chr14:105863420 C>A | 5'Flank (SNP) | VAF 8/15 reads (53%) | called by muse, varscan2
- IL16 | chr15:81311999 A>G | 3'Flank (SNP) | VAF 22/39 reads (56%) | called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.-103A>C | 5'UTR (SNP) | VAF 51/288 reads (18%) | called by muse, mutect2, varscan2
- KCTD12 | c.*724T>C | 3'UTR (SNP) | VAF 24/26 reads (92%) | catalogued as rs1438116935; called by muse, mutect2, varscan2
- KLHL23 | chr2:169750427 A>G | 3'Flank (SNP) | VAF 16/32 reads (50%) | called by muse, mutect2, varscan2
- LINC02872 | n.2705G>A | RNA (SNP) | VAF 35/71 reads (49%) | called by muse, mutect2, varscan2
- MSI2 | c.652+43C>T | Intron (SNP) | VAF 5/26 reads (19%) | called by muse, mutect2
- MSL2 | c.*1396T>A | 3'UTR (SNP) | VAF 15/35 reads (43%) | called by muse, mutect2, varscan2
- NDUFA10 | c.*3679G>T | 3'UTR (SNP) | VAF 17/36 reads (47%) | called by muse, mutect2, varscan2
- NEK1 | c.*476A>G | 3'UTR (SNP) | VAF 31/63 reads (49%) | catalogued as rs1315735244; called by muse, mutect2, varscan2
- NOL4L | c.*765A>G | 3'UTR (SNP) | VAF 22/138 reads (16%) | called by muse, mutect2, varscan2
- NUBPL | chr14:31561244 T>G | 5'Flank (SNP) | VAF 25/55 reads (45%) | called by muse, mutect2, varscan2
- PAM | c.*1742G>C | 3'UTR (SNP) | VAF 40/70 reads (57%) | called by muse, mutect2, varscan2
- PCDH11X | c.*378A>C | 3'UTR (SNP) | VAF 14/66 reads (21%) | catalogued as rs1174750393, COSV100013918; called by muse, mutect2, varscan2
- PDCD2 | c.*804G>T | 3'UTR (SNP) | VAF 25/42 reads (60%) | called by muse, mutect2, varscan2
- PHF19 | c.780-98del | Intron (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel
- PTBP3 | c.8+663A>G | Intron (SNP) | VAF 44/116 reads (38%) | called by muse, mutect2, varscan2
- RBBP7 | c.*156T>G | 3'UTR (SNP) | VAF 54/96 reads (56%) | called by muse, mutect2, varscan2
- RFTN2 | c.*762del | 3'UTR (DEL) | VAF 26/50 reads (52%) | catalogued as rs909553806; called by mutect2, varscan2
- RTN4RL2 | c.*293G>A | 3'UTR (SNP) | VAF 37/71 reads (52%) | called by muse, mutect2, varscan2
- SLC24A4 | c.881-73G>T | Intron (SNP) | VAF 3/11 reads (27%) | called by muse, mutect2
- SLC25A48 | c.679+160T>C | Intron (SNP) | VAF 158/345 reads (46%) | called by muse, mutect2, varscan2
- SLC25A53 | c.*2441A>C | 3'UTR (SNP) | VAF 9/117 reads (8%) | called by muse, mutect2
- SPART | c.*2114T>A | 3'UTR (SNP) | VAF 31/32 reads (97%) | called by muse, mutect2, varscan2
- TDRD9 | c.*162C>T | 3'UTR (SNP) | VAF 32/62 reads (52%) | called by muse, mutect2, varscan2
- TECRL | chr4:64275924 G>A | 3'Flank (SNP) | VAF 29/60 reads (48%) | catalogued as rs943606931; called by muse, mutect2, varscan2
- TENM3 | c.4892+91T>C | Intron (SNP) | VAF 7/12 reads (58%) | called by muse, varscan2
- TRIM2 | c.-49+51238G>A | Intron (SNP) | VAF 34/85 reads (40%) | called by muse, mutect2, varscan2
- VSTM2A | c.634+708G>A | Intron (SNP) | VAF 27/67 reads (40%) | catalogued as rs1340434491; called by muse, mutect2, varscan2
- WBP2NL | chr22:41998732 C>G | 5'Flank (SNP) | VAF 36/89 reads (40%) | called by muse, mutect2, varscan2
